Somatic mutation profile of tumor specimen ALCH-ADI0-TTP1-A (aliquot ALCH-ADI0-TTP1-A-1-0-D-A549-36) from ALCHEMIST case ALCH-ADI0, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 75.4 years (27,543 days).
Specimen ALCH-ADI0-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 72598d61-9c63-4b42-a775-cb78006b713d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ADI0-NB1-A (Blood Derived Normal), aliquot ALCH-ADI0-NB1-A-1-0-D-A549-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/df83f066-9121-4914-9789-5f138085618c

The open-access MAF lists 39 somatic variants for this specimen: 27 protein-altering or splice-affecting, 6 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 6, 3'UTR 3, Intron 3, Nonsense Mutation 3, Frame Shift Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 63/334 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.473G>T p.R158L | Missense Mutation (SNP) | VAF 15/44 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs587782144, CM102353, CM165595, CM994513, COSV52676395, COSV52678258, COSV52680378, COSV53545833; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADGRG7 | c.548C>T p.T183M | Missense Mutation (SNP) | VAF 36/363 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.765); catalogued as rs190503505; called by muse, mutect2, varscan2
- EYS | c.19G>A p.V7I | Missense Mutation (SNP) | VAF 26/362 reads (7%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0); catalogued as rs377622148, COSV100675758; called by muse, mutect2
- FFAR2 | c.439G>A p.V147I | Missense Mutation (SNP) | VAF 20/141 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.056); catalogued as rs771781550, COSV55831802; called by muse, mutect2, varscan2
- L1CAM | c.256G>A p.V86M | Missense Mutation (SNP) | VAF 45/198 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.187); catalogued as rs149309725; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- OR4A16 | c.700G>T p.A234S | Missense Mutation (SNP) | VAF 24/220 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.913); catalogued as rs368388243; called by muse, mutect2, varscan2
- POMT2 | c.1187C>T p.P396L | Missense Mutation (SNP) | VAF 47/685 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as rs763018692; called by muse, mutect2
- RANGAP1 | c.504A>T p.E168D | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.041); catalogued as rs1354360730; called by muse, mutect2, varscan2
- SLC25A42 | c.32G>A p.R11Q | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT tolerated (0.57); PolyPhen benign (0.01); catalogued as rs761258835, COSV59381241; called by muse, mutect2
- TNRC6B | c.3298C>T p.R1100* (on ENST00000454349 / NM_001162501.2; = p.R1047* on NM_015088.3) | Nonsense Mutation (SNP) | VAF 23/248 reads (9%) | catalogued as COSV57288112; called by muse, mutect2
- BCAS1 | c.817G>A p.D273N | Missense Mutation (SNP) | VAF 32/242 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- CIB2 | c.466G>A p.A156T | Missense Mutation (SNP) | VAF 35/148 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.911); called by muse, mutect2, varscan2
- DMD | c.8421G>A p.W2807* | Nonsense Mutation (SNP) | VAF 22/486 reads (5%) | called by muse, mutect2
- DYNC1H1 | c.8531G>T p.R2844L | Missense Mutation (SNP) | VAF 41/455 reads (9%) | SIFT tolerated (0.23); PolyPhen benign (0.055); called by muse, mutect2
- MTIF2 | c.1211G>T p.G404V | Missense Mutation (SNP) | VAF 32/620 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NDEL1 | c.775C>T p.L259F | Missense Mutation (SNP) | VAF 19/354 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NOX3 | c.1405del p.T469Lfs*4 | Frame Shift Del (DEL) | VAF 16/136 reads (12%) | called by mutect2, varscan2
- PEG3 | c.412G>T p.V138L | Missense Mutation (SNP) | VAF 64/244 reads (26%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2, varscan2
- POM121C | c.832A>C p.S278R (on ENST00000607367; = p.S36R on NM_001099415.3) | Missense Mutation (SNP) | VAF 18/411 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.085); called by muse, mutect2
- PSMD12 | c.286del p.Q96Sfs*2 | Frame Shift Del (DEL) | VAF 26/143 reads (18%) | called by mutect2, pindel, varscan2
- RGSL1 | c.209A>T p.K70I | Missense Mutation (SNP) | VAF 72/300 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SLC16A5 | c.146A>G p.N49S | Missense Mutation (SNP) | VAF 20/108 reads (19%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.977); called by muse, mutect2
- SLC5A1 | c.1486G>A p.G496R | Missense Mutation (SNP) | VAF 29/411 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- SNRNP200 | c.4691C>T p.P1564L | Missense Mutation (SNP) | VAF 16/176 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.669); called by muse, mutect2
- SOGA1 | c.1081A>T p.K361* | Nonsense Mutation (SNP) | VAF 34/278 reads (12%) | called by muse, mutect2, varscan2
- TRAF5 | c.443T>C p.V148A | Missense Mutation (SNP) | VAF 82/458 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.32); called by muse, mutect2, varscan2
- FLG | c.5889C>T p.D1963= | Silent (SNP) | VAF 75/354 reads (21%) | called by muse, mutect2, varscan2
- PAX6 | c.306C>A p.I102= | Silent (SNP) | VAF 82/539 reads (15%) | called by muse, mutect2, varscan2
- SIX5 | c.2184C>T p.L728= | Silent (SNP) | VAF 11/62 reads (18%) | called by muse, mutect2, varscan2
- TRPC4 | c.747A>G p.K249= | Silent (SNP) | VAF 16/384 reads (4%) | catalogued as rs1566139370; called by muse, mutect2
- VSIG4 | c.393T>G p.T131= | Silent (SNP) | VAF 4/34 reads (12%) | called by muse, mutect2
- WNT2 | c.969G>A p.K323= | Silent (SNP) | VAF 40/191 reads (21%) | called by muse, mutect2, varscan2
- ALK | c.*26C>T | 3'UTR (SNP) | VAF 21/302 reads (7%) | catalogued as rs987583019; called by muse, mutect2
- FBXO46 | c.*242dup | 3'UTR (INS) | VAF 10/96 reads (10%) | catalogued as rs750660858; called by pindel, varscan2
- GALK1 | c.611+11C>T | Intron (SNP) | VAF 12/82 reads (15%) | called by muse, mutect2, varscan2
- NHEJ1 | c.589-17095C>G | Intron (SNP) | VAF 24/233 reads (10%) | called by muse, mutect2, varscan2
- PYHIN1 | c.*20G>T | 3'UTR (SNP) | VAF 12/289 reads (4%) | called by muse, mutect2
- RYR1 | c.10938-48A>C | Intron (SNP) | VAF 8/88 reads (9%) | called by muse, mutect2
